Gene-level copy-number profile of tumor specimen TCGA-ZF-A9R0-01A from TCGA case TCGA-ZF-A9R0, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 82.7 years (30,222 days).
Specimen TCGA-ZF-A9R0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.3c6a1138-dfff-4d0f-86a3-c2c482a8b04b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZF-A9R0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d84138b9-082f-4df5-830d-250f0dee9a8e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 3,296; copy number 2: 9,286; copy number 3: 20,439; copy number 4: 18,861; copy number 5: 5,991; copy number 6: 1,453; copy number 7: 352; copy number 8: 83; copy number 10: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZF-A9R0-01A-11D-A38F-01): tumor purity 0.51, ploidy 3.54, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 32 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:950,849–1,367,613, 1 gene (within-gene range 0–5): SNTG2.
- chr2:1,158,310–1,580,747, 4 genes (within-gene range 0–5): AC114808.2, AC108462.1, AC105450.1, TPO.
- chr4:13,333,414–14,453,625, 19 genes (within-gene range 0–2): HSP90AB2P, RAB28, AC006445.3, LINC01097, NKX3-2, LINC01096, BOD1L1, MIR5091, AC006445.2, AC006445.1, LINC01182, AC007126.1, AC095052.1, LINC01085, AC073848.1, AC092546.1, AC006296.3, AC006296.2, AC006296.1.
- chr9:21,967,752–22,214,672, 8 genes (within-gene range 0–2): CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 455 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:216,503,246–218,918,714, 20 genes, copy number 10 (within-gene range 4–10): ESRRG, GPATCH2, SPATA17, SPATA17-AS1, UBBP2, LINC00210, AL355526.1, LINC01653, AL355526.2, RNU1-141P, RRP15, AC096638.2, AC096638.1, TGFB2-AS1, TGFB2, TGFB2-OT1, LINC02869, U3, NXNP1, LINC01710.
- chr2:81,418,723–84,040,720, 23 genes, copy number 7: CHMP4AP1, LINC01815, RNA5SP99, AC013262.1, RN7SL201P, AC079896.1, LYARP1, RNU6-685P, Y_RNA, AC010105.1, RBX1P1, MTND4P25, MTND5P27, MTND6P7, MTCYBP7, AC098817.1, DHFRP3, AC138623.1, LINC01809, RPL37P10, RNU6-1312P, CRLF3P3, ST6GALNAC2P1.
- chr13:87,672,615–87,892,472, 5 genes, copy number 8 (within-gene range 5–8): SLITRK5, AL445647.2, LINC00397, AL445647.1, TET1P1.
- chr20:6,200,989–19,056,796, 179 genes, copy number 7 (broad region; genes not listed).
- chr20:19,693,209–30,214,976, 185 genes, copy number 7–8 (broad region; genes not listed).
- chr20:54,475,593–56,786,087, 32 genes, copy number 7: DOK5, RNU4ATAC7P, RPL12P4, LINC01440, LINC01441, AL160413.1, AL109829.1, AL109828.1, CBLN4, RNA5SP487, MC3R, AL139824.2, AL139824.1, FAM210B, AURKA, CSTF1, CASS4, RPL39P, RTF2, GCNT7, FAM209A, AL109806.1, FAM209B, AL109806.2, LINC01716, RPS4XP3, TFAP2C, RNU6-1146P, RN7SL170P, PTMAP6, AL133232.1, RNU6-929P.
- chr20:60,087,826–61,083,750, 9 genes, copy number 7 (within-gene range 6–7): MIR646HG, MIR646, MTCO2P1, MIR4533, MIR548AG2, AL117372.1, AL139348.1, AL121910.1, LINC01718.
- chr20:61,267,525–61,370,855, 2 genes, copy number 7: AL365229.1, BX640515.1.

Autosomal genes at a single copy (total copy number 1): 939. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
